FM case AD16435 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/b9608dcd-69ed-4b1c-b15e-b8d2d2ee831a

Male, 81.3 years: Melanoma, NOS (ICD-O-3 8720/3) of the skin; metastasis biopsied or resected from the parotid gland. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Metastatic.
